ALCHEMIST case ALCH-AEF2 — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/2583e3d8-1acc-486d-b614-230e9defcb6f

Demographics
Sex at birth: male.

Diagnoses (1)
1. Adenocarcinoma in situ, NOS: Age at diagnosis: 63.9 years (23,356 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-AEF2-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-AEF2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-AEF2-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 25; Percent tumor nuclei: 25; Percent normal cells: 63; Percent necrosis: 2; Percent stromal cells: 10; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
